Somatic mutation profile of tumor specimen TCGA-KK-A8IH-01A (aliquot TCGA-KK-A8IH-01A-11D-A364-08) from TCGA case TCGA-KK-A8IH, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 50.8 years (18,560 days).
Specimen TCGA-KK-A8IH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 771b0dbe-1c7d-4573-b3d0-bff9139d2481.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8IH-11A (Solid Tissue Normal), aliquot TCGA-KK-A8IH-11A-11D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cb5deae-b386-4a0c-8a5a-e80e48eef18a

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Frame Shift Del 2, Intron 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIRC5 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV100051413; called by muse, mutect2, varscan2
- CES1 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as COSV100828741; called by muse, mutect2, varscan2
- CFAP70 | c.3192C>G p.N1064K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV100160847; called by muse, mutect2, varscan2
- FAM13A | c.2210A>G p.Q737R | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV99984259; called by muse, mutect2, varscan2
- GOT2 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV99803839; called by muse, mutect2, varscan2
- HMGCL | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs754663896, COSV99354029; called by muse, mutect2, varscan2
- KCNK2 | c.1219C>A p.L407M (on ENST00000444842 / NM_001017425.3; = p.L392M on NM_014217.4) | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.015); catalogued as COSV101222259; called by muse, mutect2, varscan2
- KCNK5 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100851892; called by muse, mutect2, varscan2
- MTMR7 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs953439770, COSV99472611; called by muse, varscan2
- OCA2 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.584); catalogued as rs759401481, COSV100668226; called by muse, mutect2, varscan2
- PCLO | c.11395C>T p.R3799* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV61656825; called by muse, mutect2, varscan2
- PIK3CB | c.2884T>A p.Y962N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.06); catalogued as COSV56687617; called by muse, mutect2
- SNX19 | c.2386G>A p.D796N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.15); catalogued as COSV99773365; called by muse, mutect2, varscan2
- TRIM37 | c.861C>G p.S287R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs779597971, COSV99233186; called by mutect2, varscan2
- CAMKMT | c.244del p.E82Kfs*22 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- MCM8 | c.1942_1947del p.E648_R649del | In Frame Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel
- VAPA | c.684_685del p.P229Ffs*23 (on ENST00000400000 / NM_194434.3; = p.P274Ffs*23 on NM_003574.6) | Frame Shift Del (DEL) | VAF 10/103 reads (10%) | called by mutect2, pindel
- ACVR1C | c.1281G>T p.S427= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs750781986, COSV54646784, COSV99694880; called by muse, mutect2, varscan2
- CIT | c.1776T>G p.S592= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV99950335; called by muse, mutect2
- GUCY2C | c.3195C>T p.T1065= | Silent (SNP) | VAF 69/176 reads (39%) | catalogued as COSV53791325, COSV99663877; called by muse, mutect2, varscan2
- IL3RA | c.1035C>T p.I345= | Silent (SNP) | VAF 102/284 reads (36%) | catalogued as rs201211678, COSV100452219, COSV58430123, COSV58433847; called by muse, mutect2, varscan2
- KLHL15 | c.828T>C p.R276= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV100044305; called by muse, mutect2
- MAGEA4 | c.267C>T p.S89= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99367623; called by muse, mutect2, varscan2
- ZCCHC14 | c.756G>A p.P252= (on ENST00000268616; = p.P389= on NM_015144.3) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs747295626, COSV99234253; called by muse, mutect2, varscan2
- MARCHF1 | c.163-13C>G | Intron (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99921936; called by muse, mutect2, varscan2
